Surgical pathology report (de-identified scan), TCGA case TCGA-02-2486, project TCGA-GBM (Glioblastoma Multiforme), tissue source site MD Anderson Cancer Center, specimen TCGA-02-2486-01A (Primary Tumor).

TCGA-02-2486

DIAGNOSIS

(A, B) BRAIN BIOPSIES AND RESECTION DESIGNATED RECURRENT LEFT TEMPORAL BRAIN TUMOR:
GLIOBLASTOMA (WHO GRADE IV). (SEE COMMENT)

COMMENT

Multiple sections show necrosis of more than 50% of the tissue received. In addition, many small blood vessels are hyalinized, evidence of therapy effect.

GROSS DESCRIPTION

(A) RECURRENT LEFT TEMPORAL BRAIN TUMOR - Multiple pieces of friable, pink-yellow tissue measuring approximately 1.5 x 1.5 x 0.5 cm in aggregate. A smear preparation is performed. Additional tissue is submitted for frozen section diagnosis. The remainder is submitted in toto for permanent section.

SECTION CODE: A1, frozen section; A2-A4, permanent section.

DX: GLIOBLASTOMA.

(B) RECURRENT LEFT TEMPORAL BRAIN TUMOR - Multiple pale gray brain tissue (4.2 x 3.8 x 1.3 cm in aggregate) ranging from 0.4 x 0.4 x 0.3 cm to 4.0 x 2.5 x 1.2 cm including one pink-tan plug (0.5 x 0.5 x 0.3 cm). The specimen is serially sectioned and entirely submitted in B1-B8.

CLINICAL HISTORY

History of glioblastoma

CONSULTANT(S)

SNOMED CODES

T-A2000, M-94403

Source: NCI Genomic Data Commons file 6082eeb7-cde1-46b1-b7d7-f84596dbf925 (TCGA-02-2486.26E31C62-06A2-4906-A1D5-985DC0F961E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).